Surgical pathology report (de-identified scan), TCGA case TCGA-12-3652, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3652-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

TCGA-12-3652

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Left parietal neoplasm 191.3. MRI Findings: Post gadolinium thin section imaging was obtained through the brain with fiducial markers in place for the purposes of preoperative localization. A peripherally enhancing mass in the left parietal region, with a broad contact against the dura is again seen, which is not significantly changed compared with prior outside MRI. There is mass effect results in effacement of the atrium and occipital horn of the left lateral ventricle, as well as partial effacement of the left ambient / quadrigeminal plate cistern by the posterior medial temporal lobe. This also remains unchanged. Low T1 signal in the left parietal lobe is not significantly changed in distribution given differences in technique.

GROSS EXAMINATION:

A. "Brain tissue (AF1-2)", received fresh for frozen section is a 5 x 5 x 1.5 cm fragment of brown-tan soft tissue. Sectioning reveals a focally necrotic and hemorrhagic surface. Representative sections are frozen as AF1-2 and the frozen section remnants are submitted in blocks A1-2, respectively. Additional representative sections are submitted in blocks A3-8, with the remainder retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1-2-high grade glioma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (77% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (96% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (67% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (73% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - LOSS (48% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 2]
CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (42% OF TUMOR CELLS EXHIBIT LOSS)
4 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:
IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV); [REDACTED]

LEUCOCYTE COMMON ANTIGEN (LCA): 5% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (10% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 80% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 10% OF TUMOR CELLS)

S6 - NEGATIVE (2+ IN 10% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 10% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD:
[REDACTED]

Source: NCI Genomic Data Commons file efd960df-71b3-478a-9ac5-838c3fa8da12 (TCGA-12-3652.EE607E3D-3AED-4B43-A0CF-FF0E4CA7375B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).